Somatic mutation profile of tumor specimen TARGET-10-PATDBU-09A (aliquot TARGET-10-PATDBU-09A-01D) from TARGET case TARGET-10-PATDBU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,551 days).
Specimen TARGET-10-PATDBU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d43630-a6fd-43f6-9d35-a6374c77d270.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDBU-10A (Blood Derived Normal), aliquot TARGET-10-PATDBU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/749c607d-4e7a-4bfc-8206-f18ffe2779da

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2, Splice Region 1, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by mutect2, varscan2
- DNAH8 | c.1743C>T p.Y581= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as rs762160890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.1307G>A p.R436Q (on ENST00000339876 / NM_001378329.1; = p.R447Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.247); catalogued as rs756666571, COSV58359751; called by muse, mutect2, varscan2
- RBM46 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as rs1322290101, COSV55977234; called by mutect2, varscan2
- TNR | c.3668G>A p.R1223H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs142934156, COSV54900246; called by muse, mutect2, varscan2
- USP7 | c.1447_1450delinsTTTTTAGTGGT p.D483Ffs*10 | Frame Shift Ins (INS) | VAF 12/61 reads (20%) | called by pindel, varscan2*
- ANK1 | c.4722G>A p.T1574= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs572098639, COSV55884518; called by muse, mutect2, varscan2
- CDC25B | c.1710G>A p.R570= (on ENST00000245960 / NM_021873.3; = p.R556= on NM_004358.4) | Silent (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- FBN3 | c.1698C>T p.G566= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs192697571; called by muse, mutect2
- PRR23A | c.468C>T p.Y156= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs749352615, COSV67214839; called by muse, mutect2, varscan2
- DPYSL2 | c.-19A>T | 5'UTR (SNP) | VAF 17/90 reads (19%) | catalogued as rs768012686, COSV60785380; called by muse, mutect2, varscan2
- LIMCH1 | c.935+7551del | Intron (DEL) | VAF 17/37 reads (46%) | catalogued as rs1198817073; called by mutect2, varscan2
- MIR206 | n.72_73del | RNA (DEL) | VAF 4/23 reads (17%) | called by pindel, varscan2
- SNX29 | c.1402+9221C>T | Intron (SNP) | VAF 19/36 reads (53%) | catalogued as rs765695469; called by muse, mutect2, varscan2
